CCDI case PBCBDL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2b1ca4a9-9cae-44af-9404-13944be487c4

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,391 days).

Biospecimens (3 samples)
- Sample 0DN3R5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN3SE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN3SQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
